CCDI case PBCMFW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6829e387-22d0-4803-acce-6123667b36f2

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 2.1 years (755 days).

Biospecimens (3 samples)
- Sample 0DWBC0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWBCF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DWBCL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
